Surgical pathology report (de-identified scan), TCGA case TCGA-QR-A70O, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site National Institutes of Health, specimen TCGA-QR-A70O-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology

Final Results

Surgical Pathology

Final

CASE NUMBER:

DIAGNOSIS: Adrenal gland, left, resection: Pheochromocytoma, 2.8 cm.

Immunoperoxidase and in-situ hybridization tests performed here and used for diagnosis were developed and their performance characteristics determined by the Laboratory of Pathology. They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has also determined that such clearance or approval is not necessary. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

CLINICAL INFORMATION: Brief Clinical History: L-adrenal-pheo-Specimen

Taken For Protocol: 01

- Yes Allocate Order to Protocol:

PROCEDURE: Pre-Operative Diagnosis: pheochromocytoma L adrenal gl
Post-Operative

Diagnosis: same Operative Findings: as expected

SPECIMENS SUBMITTED: 1. ADRENAL GLAND, LEFT

GROSS DESCRIPTION: Received fresh from the Operating Room in a container labeled with the patient's name, medical record number, and "left adrenal gland" is a red-tan ovoid nodule measuring 4.5 x 4.0 x 2.3 cm. Nodule and disrupted fragment 2.8 x 2.2 x 1.0 cm, attached fat 3.5 x 3.5 x 1.0 cm. Tumor nodules are inked in black. Gross photographs are taken. Approximately 3-4 mm piece was given to

. Approximately 50% of the tissue is procured by . The remainder of the specimen is placed in formalin and submitted to Pathology for permanent processing. The procurement was performed by

Also received and procured entirely for research is a specimen labeled as "left periadrenal fat", consists of unremarkable adipose tissue measuring 0.5 x 0.4 x 0.3 cm, procurement for procurement by

at . Received at Surgical Pathology, the specimen matches the previous description. It is serially sectioned and representative sections are submitted in 8 white cassettes labeled

Gross Description dictated by .

No consultants

Accessioned:

Final Report Signed Out:

<Resident Signature>

[page 2 of 2]
Surgical Pathology

Final Results

<Sign Out Dr. Signature>

Date Report Signed:

Confidential Patient Information. Unauthorized disclosure is prohibited by the Federal Privacy Act of 1974.

JobID:

Requested By:

Do not file in Medical Record

Source: NCI Genomic Data Commons file b45b1d28-c585-422f-8c9d-72592e7be58d (TCGA-QR-A70O.CCDF780F-2C65-431E-8DA0-A64651233D76.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).